Gene-level copy-number profile of tumor specimen TCGA-2H-A9GM-01A from TCGA case TCGA-2H-A9GM, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 53.3 years (19,484 days).
Specimen TCGA-2H-A9GM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.f1a2ad52-2efb-4bb3-ac06-ce1a5b6b0428.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GM-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 833 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/19636735-89df-4f08-8c45-1b2ec8a7d73e

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 90; copy number 1: 258; copy number 2: 1,103; copy number 3: 8,653; copy number 4: 16,896; copy number 5: 18,809; copy number 6: 2,879; copy number 7: 4,589; copy number 8: 1,648; copy number 9: 1,339; copy number 10: 1,208; copy number 11: 502; copy number 12: 361; copy number 13: 193; copy number 14: 237; copy number 15: 230; copy number 16: 48; copy number 17: 154; copy number 18: 177; copy number 21: 96; copy number 22: 13; copy number 23: 12; copy number 24: 107; copy number 26: 44; copy number 27: 62; copy number 34: 6; copy number 35: 6; copy number 36: 59; copy number 42: 11.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr18:58,044,226–62,443,126, 86 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2,318 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–147,788,953, 147 genes, copy number 11 (broad region; genes not listed).
- chr1:161,258,745–162,370,475, 39 genes, copy number 11 (within-gene range 6–16): PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, AL831711.1, FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1, RPL31P11, Y_RNA, FCRLA, FCRLB, RN7SL466P, DUSP12, AL359541.1, ATF6, AL391825.1, OLFML2B, AL590408.1, NOS1AP, AL450163.1, MIR4654.
- chr1:163,509,484–164,357,364, 6 genes, copy number 15–22: RNA5SP63, AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6.
- chr1:164,639,565–164,703,309, 3 genes, copy number 15: RNU6-171P, AL391001.1, Metazoa_SRP.
- chr1:230,002,372–231,819,244, 41 genes, copy number 12 (within-gene range 9–12): LINC01736, GALNT2, AL136988.2, AL136988.1, PGBD5, AL133516.1, LINC01737, AL158214.1, COG2, AL158214.2, AGT, AL512328.1, CAPN9, RNA5SP79, AL118511.2, C1orf198, AL118511.1, AL118511.4, AL118511.3, RN7SL837P, TTC13, ARV1, FAM89A, MIR1182, AL732414.1, AL109810.1, TRIM67, TRIM67-AS1, C1orf131, GNPAT, RNA5SP80, EXOC8, SPRTN, AL117352.1, EGLN1, AL445524.2, SNRPD2P2, AL445524.1, TSNAX, TSNAX-DISC1, LINC00582.
- chr1:231,670,635–231,670,750, 1 gene, copy number 12: RNU5A-5P.
- chr1:233,614,106–236,604,516, 89 genes, copy number 11 (within-gene range 7–11) (broad region; genes not listed).
- chr4:51,843,000–52,097,299, 8 genes, copy number 15: DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18.
- chr4:58,524,515–64,433,215, 39 genes, copy number 11–14: LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1, LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1, AC074087.2, AC074087.1, HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1, AC093730.1, TECRL, RNU6-191P, DPP3P1.
- chr6:39,329,990–39,725,408, 1 gene, copy number 22 (within-gene range 3–22): KIF6.
- chr6:39,553,811–46,704,319, 188 genes, copy number 14–27 (broad region; genes not listed).
- chr6:46,852,522–47,832,780, 17 genes, copy number 14–42: ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P.
- chr7:65,873,074–73,770,270, 141 genes, copy number 12–14 (broad region; genes not listed).
- chr8:49,906,863–50,796,692, 3 genes, copy number 13–22 (within-gene range 4–22): AC023762.1, SNTG1, AC090539.1.
- chr8:79,891,553–81,842,866, 60 genes, copy number 11–18: AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, AC012533.1, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36.
- chr8:87,788,562–89,833,564, 16 genes, copy number 12–14: SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74, KRT8P4, AF117829.1, RIPK2, COX6B1P6, AF117829.2.
- chr8:97,772,313–104,484,465, 164 genes, copy number 11–13 (broad region; genes not listed).
- chr8:105,546,089–111,757,710, 64 genes, copy number 13 (broad region; genes not listed).
- chr8:112,643,493–112,643,583, 1 gene, copy number 16: MIR2053.
- chr8:118,620,498–131,040,909, 195 genes, copy number 13–36 (within-gene range 8–36) (broad region; genes not listed).
- chr8:139,727,725–140,458,579, 1 gene, copy number 11 (within-gene range 9–11): TRAPPC9.
- chr8:139,931,172–141,002,216, 12 genes, copy number 11 (within-gene range 3–11): C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1.
- chr16:34,962,970–35,912,516, 81 genes, copy number 17–18 (broad region; genes not listed).
- chr17:43,412,427–43,787,620, 16 genes, copy number 12: RNU6-470P, MIR2117HG, MIR2117, RNU6-406P, RNU6-971P, AC087650.1, DHX8, ETV4, Metazoa_SRP, MEOX1, LINC02594, WHSC1L2P, SOST, DUSP3, CFAP97D1, AC003098.1.
- chr18:1,883,524–27,595,164, 463 genes, copy number 11–27 (broad region; genes not listed).
- chr18:37,960,220–37,992,413, 1 gene, copy number 16: AC108452.1.
- chr18:41,341,319–50,195,147, 135 genes, copy number 12–34 (within-gene range 1–37) (broad region; genes not listed).
- chr18:62,523,025–69,849,087, 81 genes, copy number 15–17 (broad region; genes not listed).
- chr18:73,324,941–80,247,514, 136 genes, copy number 11–21 (broad region; genes not listed).
- chr20:19,208,652–26,251,546, 169 genes, copy number 15–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 255. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
